Somatic mutation profile of tumor specimen TCGA-HT-7855-01A (aliquot TCGA-HT-7855-01A-11D-2395-08) from TCGA case TCGA-HT-7855, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 39.7 years (14,496 days).
Specimen TCGA-HT-7855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca842222-0b43-40f1-b9a3-73960eaa8e8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7855-10A (Blood Derived Normal), aliquot TCGA-HT-7855-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2dd9252-2ef3-4865-87db-834956525dd1

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Frame Shift Del 6, In Frame Del 6, Nonsense Mutation 3, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 45/95 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.1636_1638del p.K546del | In Frame Del (DEL) | VAF 36/179 reads (20%) | hotspot (GDC flag); catalogued as rs876657378; called by pindel, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 30/32 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by mutect2, varscan2
- ACAT2 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58459242; called by muse, mutect2, varscan2
- ARHGEF2 | c.1333A>G p.I445V (on ENST00000361247 / NM_001162383.2; = p.I417V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); catalogued as COSV58112081; called by muse, mutect2, varscan2
- C12orf71 | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV70282743; called by muse, mutect2, varscan2
- CCNYL1 | c.519+3_519+6del p.X173_splice (on ENST00000295414 / NM_001330218.2; = p.X103_splice on NM_152523.2) | Splice Site (DEL) | VAF 7/41 reads (17%) | catalogued as rs1396063963; called by mutect2, pindel
- EID2B | c.14C>G p.T5S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.022); catalogued as COSV58319133; called by muse, mutect2, varscan2
- GBP2 | c.1254_1256del p.E418del | In Frame Del (DEL) | VAF 36/216 reads (17%) | catalogued as rs765107402; called by pindel, varscan2
- GEMIN5 | c.472_475del p.T158Vfs*8 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | catalogued as rs1446108068; called by mutect2, pindel
- HID1 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs752532048, COSV100172799; called by muse, mutect2, varscan2
- IFI16 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs868695062, COSV55535138; called by muse, mutect2, varscan2
- IPO9 | c.513A>G p.T171= | Splice Region (SNP) | VAF 20/48 reads (42%) | catalogued as COSV64234027; called by muse, mutect2, varscan2
- MUC5AC | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.18); catalogued as rs866043302; called by muse, mutect2
- MYO1F | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs780174055, COSV57796087; called by muse, mutect2, varscan2
- OR1J4 | c.184_186del p.F62del | In Frame Del (DEL) | VAF 122/284 reads (43%) | catalogued as rs773216211; called by pindel, varscan2
- OR51B2 | c.347T>C p.M116T | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1223071198, COSV60916921; called by muse, mutect2
- RHOH | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as rs200653414, COSV67805884; called by muse, mutect2, varscan2
- SLC12A2 | c.925T>C p.S309P | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.356); catalogued as COSV52472292; called by muse, mutect2, varscan2
- SLC28A2 | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV61664278; called by muse, mutect2, varscan2
- SLC6A3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs138948519; ClinVar: uncertain significance; called by muse, mutect2
- SLCO2A1 | c.1771C>T p.R591* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as rs768030732, COSV60486478; called by mutect2, varscan2
- STK31 | c.3018T>A p.C1006* | Nonsense Mutation (SNP) | VAF 59/112 reads (53%) | catalogued as COSV63456845; called by muse, mutect2, varscan2
- TMPRSS6 | c.1451C>G p.A484G | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV60979441; called by muse, mutect2
- YTHDC1 | c.439_441del p.P147del | In Frame Del (DEL) | VAF 23/58 reads (40%) | catalogued as rs751051650; called by mutect2, pindel, varscan2
- ANK2 | c.7309_7310del p.L2437Gfs*9 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | called by pindel, varscan2
- ATRX | c.4040_4041del p.V1347Efs*2 | Frame Shift Del (DEL) | VAF 20/37 reads (54%) | called by pindel, varscan2
- CALCOCO1 | c.874_876del p.E292del | In Frame Del (DEL) | VAF 33/77 reads (43%) | called by mutect2, pindel, varscan2
- ELOA | c.544_545del p.K182Efs*14 | Frame Shift Del (DEL) | VAF 42/169 reads (25%) | called by mutect2, pindel, varscan2
- RELL2 | c.293_295del p.G98del | In Frame Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- SEC22A | c.483_484insGATGGAGTCC p.N162Dfs*13 | Frame Shift Ins (INS) | VAF 30/170 reads (18%) | called by mutect2, varscan2
- UXS1 | c.1240_1243del p.K414Dfs*33 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | called by pindel, varscan2
- ZXDC | c.923_926del p.F308Sfs*3 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | called by mutect2, pindel, varscan2
- BMP6 | c.543G>A p.P181= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs761569040, COSV51666570; called by muse, mutect2
- C5orf34 | c.1695A>G p.E565= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV60930550; called by muse, mutect2
- FBXO33 | c.1137C>T p.I379= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs144987416; called by muse, mutect2, varscan2
- ICAM3 | c.1089T>C p.N363= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV50329252; called by muse, mutect2, varscan2
- IL18R1 | c.285T>A p.S95= | Silent (SNP) | VAF 15/165 reads (9%) | catalogued as COSV52124984; called by muse, mutect2
- KATNIP | c.231T>C p.N77= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as rs1567227035, COSV55182799; called by muse, mutect2, varscan2
- SCGB2A2 | c.51C>T p.Y17= | Silent (SNP) | VAF 97/208 reads (47%) | catalogued as rs137975337; called by muse, mutect2, varscan2
